Somatic mutation profile of tumor specimen C3N-01368-03 (aliquot CPT0093590009) from CPTAC case C3N-01368, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.0 years (24,115 days).
Specimen C3N-01368-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 753fae7b-eb67-4f56-aa5f-273038ef8638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01368-31 (Blood Derived Normal), aliquot CPT0093620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6216790-c5bb-4c06-9957-4ff07c834563

The open-access MAF lists 63 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 17, Intron 4, Nonsense Mutation 3, Splice Region 3, RNA 2, In Frame Del 1, Frame Shift Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 119/158 reads (75%) | catalogued as rs1554825165, CM128489, COSV64288514, COSV64302282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.3748C>T p.P1250S | Missense Mutation (SNP) | VAF 143/369 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV61263487; called by muse, mutect2, varscan2
- ADAMTS12 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs755320251; called by muse, mutect2, varscan2
- ALMS1 | c.11177G>C p.G3726A | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV52503198; called by muse, mutect2, varscan2
- ATM | c.7043C>T p.T2348M | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99589678; called by muse, mutect2, varscan2
- CD244 | c.923C>T p.T308M (on ENST00000368033 / NM_001166663.2; = p.T303M on NM_016382.4) | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs147688271; called by muse, mutect2, varscan2
- CTSG | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.181); catalogued as rs1310147398; called by muse, mutect2, varscan2
- DNAH14 | c.539C>T p.T180M (on ENST00000445597; = p.T3M on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as rs753425198, COSV64780661; called by muse, mutect2, varscan2
- FRYL | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV51962992; called by muse, mutect2, varscan2
- GIN1 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1290221026; called by muse, mutect2, varscan2
- GNAI1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs910988907, COSV100650337, COSV63522913; called by muse, mutect2, varscan2
- GNPDA2 | c.528del p.D177Ifs*10 | Frame Shift Del (DEL) | VAF 18/145 reads (12%) | catalogued as COSV99776806; called by mutect2, pindel, varscan2
- GOLGA3 | c.2814G>A p.S938= | Splice Region (SNP) | VAF 51/110 reads (46%) | catalogued as rs372071151; called by muse, mutect2, varscan2
- IL17RE | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 96/252 reads (38%) | catalogued as rs144881083; called by muse, mutect2, varscan2
- KPRP | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100908704, COSV64222577; called by muse, mutect2, varscan2
- LRTM2 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs751469692, COSV54566553; called by muse, mutect2, varscan2
- MET | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 164/574 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.159); catalogued as rs866873279; called by muse, mutect2, varscan2
- MUL1 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as rs768507910; called by muse, mutect2, varscan2
- OR2A42 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 197/1298 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs764203936, COSV66955789; called by muse, mutect2, varscan2
- PCLO | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 149/496 reads (30%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs1375996909, COSV100438128; called by muse, mutect2, varscan2
- SLC1A6 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as rs764660271, COSV55671195; called by muse, mutect2, varscan2
- SLC7A5 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 172/440 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334751026, COSV55366569; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866G>T p.G622= (on ENST00000540229 / NM_001371097.1; = p.R561S on NM_001009562.4) | Splice Region (SNP) | VAF 38/101 reads (38%) | catalogued as rs768961254; called by muse, mutect2, varscan2
- TEX13C | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 116/141 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs1364235609; called by muse, mutect2, varscan2
- ARFGEF1 | c.5154C>G p.N1718K | Missense Mutation (SNP) | VAF 123/297 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC73 | c.791A>T p.E264V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ETS1 | c.-14G>A | Splice Region (SNP) | VAF 62/133 reads (47%) | called by muse, mutect2, varscan2
- FLG2 | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KRTAP11-1 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LPXN | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, mutect2
- NUP37 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- PDE4DIP | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 110/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE5A | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC41A1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 151/375 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- SMG6 | c.2705A>C p.K902T | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCP11 | c.906G>A p.W302* (on ENST00000512012; = p.W240* on NM_018679.5) | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- TMEM79 | c.1024_1029del p.Y342_G343del | In Frame Del (DEL) | VAF 86/242 reads (36%) | called by mutect2, pindel, varscan2
- TTN | c.35249C>T p.P11750L (on ENST00000591111; = p.P10823L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/253 reads (39%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN4 | c.1056T>C p.N352= | Silent (SNP) | VAF 115/310 reads (37%) | catalogued as rs1157629096, COSV61871058; called by muse, mutect2, varscan2
- CYP4Z1 | c.966T>C p.A322= | Silent (SNP) | VAF 100/239 reads (42%) | called by muse, mutect2, varscan2
- DISP1 | c.1764G>A p.K588= | Silent (SNP) | VAF 159/422 reads (38%) | called by muse, mutect2, varscan2
- HACL1 | c.1017A>G p.T339= | Silent (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- IDH1 | c.1005C>G p.A335= | Silent (SNP) | VAF 115/342 reads (34%) | called by muse, mutect2, varscan2
- LIPK | c.336C>T p.D112= | Silent (SNP) | VAF 47/64 reads (73%) | catalogued as rs775737000; called by muse, mutect2, varscan2
- LOXHD1 | c.3165C>T p.G1055= | Silent (SNP) | VAF 96/294 reads (33%) | catalogued as rs768431469, COSV100190587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MATN4 | c.1494G>A p.T498= (on ENST00000372754; = p.T457= on NM_003833.4) | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs763095983; called by muse, mutect2, varscan2
- MUC16 | c.18735C>T p.T6245= | Silent (SNP) | VAF 91/212 reads (43%) | called by muse, mutect2, varscan2
- OR5H6 | c.150A>C p.I50= (on ENST00000642105; = p.I34= on NM_001005479.2) | Silent (SNP) | VAF 110/349 reads (32%) | called by muse, mutect2
- RBM47 | c.1008G>A p.A336= | Silent (SNP) | VAF 80/213 reads (38%) | called by muse, mutect2, varscan2
- RNF31 | c.2718C>T p.Y906= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as rs759092404, COSV100141652; called by muse, mutect2, varscan2
- SPHKAP | c.3216C>T p.G1072= | Silent (SNP) | VAF 73/180 reads (41%) | catalogued as rs746620324, COSV60883316; called by muse, mutect2, varscan2
- TBC1D20 | c.306C>T p.D102= | Silent (SNP) | VAF 13/188 reads (7%) | catalogued as rs1307609326; called by muse, mutect2
- TNPO3 | c.1032C>T p.N344= | Silent (SNP) | VAF 56/190 reads (29%) | called by muse, mutect2, varscan2
- UCP3 | c.771C>T p.L257= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as rs760694580, COSV58368723; called by muse, mutect2, varscan2
- USH2A | c.10134T>C p.P3378= | Silent (SNP) | VAF 123/272 reads (45%) | called by muse, mutect2, varscan2
- CAST | c.951+891G>C | Intron (SNP) | VAF 18/167 reads (11%) | catalogued as COSV57781944; called by muse, mutect2, varscan2
- CHID1 | c.-24G>A | 5'UTR (SNP) | VAF 97/213 reads (46%) | called by muse, mutect2, varscan2
- GDAP1 | c.*2192G>T | 3'UTR (SNP) | VAF 66/156 reads (42%) | called by muse, mutect2, varscan2
- KDM6B | c.4909-24C>G | Intron (SNP) | VAF 39/91 reads (43%) | catalogued as rs371340269; called by muse, mutect2, varscan2
- NOC2LP2 | n.248C>T | RNA (SNP) | VAF 146/357 reads (41%) | catalogued as rs766098223; called by muse, mutect2, varscan2
- PNPO | c.138+30G>A | Intron (SNP) | VAF 25/48 reads (52%) | called by muse, varscan2
- RGS11 | c.657+63C>T | Intron (SNP) | VAF 48/122 reads (39%) | catalogued as rs141327278, COSV51454006; called by muse, mutect2, varscan2
- SPATA31C2 | n.334_336del | RNA (DEL) | VAF 54/371 reads (15%) | catalogued as rs753012650; called by pindel, varscan2
